Somatic mutation profile of tumor specimen TCGA-UF-A71E-01A (aliquot TCGA-UF-A71E-01A-31D-A34J-08) from TCGA case TCGA-UF-A71E, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 63.2 years (23,071 days).
Specimen TCGA-UF-A71E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99463412-b5ce-4c7e-b862-7e5f3b024de9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A71E-10B (Blood Derived Normal), aliquot TCGA-UF-A71E-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0588907c-49d1-4627-9151-8c3968c1f750

The open-access MAF lists 178 somatic variants for this specimen: 119 protein-altering or splice-affecting, 55 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 55, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Intron 2, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 51/73 reads (70%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs377450718; called by muse, mutect2, varscan2
- ADAMTS2 | c.2896A>T p.S966C | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV99280810; called by muse, mutect2, varscan2
- ADCY5 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs780961726, COSV71902003; called by muse, mutect2, varscan2
- ADGRF1 | c.2293G>C p.V765L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs758758399, COSV99346921; called by muse, mutect2, varscan2
- ADGRF1 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99346924; called by muse, mutect2, varscan2
- ADRA1D | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101062876; called by muse, mutect2, varscan2
- ADRB1 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV100992249; called by muse, mutect2, varscan2
- AIFM3 | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777698722, COSV99301240; called by muse, mutect2, varscan2
- AKAP7 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319948892, COSV99541279; called by muse, mutect2, varscan2
- ALB | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs72552709, CM910023, COSV99890657; ClinVar: other; called by muse, mutect2, varscan2
- ANKRD53 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.79); catalogued as COSV99721212; called by muse, mutect2, varscan2
- ANKS1B | c.1934C>A p.P645H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV101612649, COSV61346658; called by muse, mutect2, varscan2
- AOC2 | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99519922; called by muse, mutect2, varscan2
- ATP5F1A | c.1578C>G p.I526M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99958718; called by muse, mutect2, varscan2
- BOC | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 107/382 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs764454159, COSV99847992; called by muse, mutect2, varscan2
- CCDC6 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV54056655, COSV99569087; called by muse, mutect2, varscan2
- CCDC7 | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 110/267 reads (41%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.184); catalogued as rs1424356002, COSV56549803; called by muse, mutect2
- CCSER2 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.588); catalogued as COSV99825414; called by muse, mutect2, varscan2
- CD200R1 | c.677G>A p.S226N (on ENST00000471858 / NM_170780.3; = p.S249N on NM_138806.4) | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV99866723; called by muse, mutect2, varscan2
- CDC23 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV101202975; called by muse, mutect2, varscan2
- CDH9 | c.588A>T p.K196N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99141439; called by muse, mutect2, varscan2
- CHST12 | c.1140G>T p.W380C | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324291; called by muse, mutect2, varscan2
- CLCN2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs770808807, COSV99658195; called by muse, mutect2, varscan2
- CMYA5 | c.6791A>T p.E2264V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV101483807; called by muse, mutect2, varscan2
- COL22A1 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs749051506, COSV100275820, COSV100276187; called by muse, mutect2, varscan2
- CREM | c.583A>G p.T195A (on ENST00000429130; = p.T162A on NM_181571.3) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV100414956; called by muse, mutect2, varscan2
- CYTH4 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs372562479; called by muse, mutect2, varscan2
- DCAF12L1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs756928184, COSV100948072; called by muse, mutect2, varscan2
- DCAF4L2 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100150478; called by muse, mutect2, varscan2
- DMD | c.5932C>T p.R1978C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); catalogued as COSV63770409; called by muse, mutect2, varscan2
- DOCK2 | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201322810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYSL4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390249466, COSV100633816; called by muse, mutect2, varscan2
- DYNC1H1 | c.10888G>A p.G3630S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794373; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.534); catalogued as COSV100668367; called by muse, mutect2, varscan2
- EPHA5 | c.1527G>C p.K509N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761446077, COSV99895928; called by muse, mutect2, varscan2
- ESRRA | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); catalogued as rs1292658094, COSV99134425, COSV99134746; called by muse, mutect2, varscan2
- FAP | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99501645; called by muse, mutect2, varscan2
- FASTKD3 | c.1666C>G p.P556A | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99242360; called by muse, mutect2
- FBN1 | c.7846A>T p.I2616F | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as CM077250, COSV100353980; called by muse, mutect2, varscan2
- FGD5 | c.994A>T p.N332Y | Missense Mutation (SNP) | VAF 166/196 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV99547191; called by muse, mutect2, varscan2
- FRAS1 | c.11711C>T p.A3904V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs750578354, COSV53594701; called by muse, mutect2, varscan2
- GFI1B | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1462798363, COSV100253925; called by muse, mutect2
- GLUD2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV60152410; called by muse, mutect2, varscan2
- GRM7 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs781301094, COSV63150459; called by muse, mutect2, varscan2
- H3C11 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV100137683, COSV58899983; called by muse, mutect2, varscan2
- HDAC3 | c.1154T>G p.L385R | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as COSV100539395; called by muse, mutect2
- HERC2 | c.9505A>T p.T3169S | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV99870724; called by muse, mutect2, varscan2
- HEXA | c.412+1G>T p.X138_splice | Splice Site (SNP) | VAF 35/82 reads (43%) | catalogued as CS941496, COSV99173667; called by muse, mutect2, varscan2
- HLA-B | c.742C>A p.Q248K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs72558120, COSV101317792, COSV69522412; called by muse, mutect2, varscan2
- IGLV2-8 | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 66/476 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs7510777; called by muse, varscan2
- IMPACT | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.297); catalogued as COSV99408759; called by muse, mutect2, varscan2
- IMPG2 | c.2177C>T p.S726F | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99514704; called by muse, mutect2, varscan2
- KEAP1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1040740503, COSV50633622, COSV50635967, COSV50650015; called by muse, mutect2, varscan2
- KLHL4 | c.1475C>G p.T492R | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100909078; called by muse, mutect2, varscan2
- KRTAP4-1 | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1456467971, COSV100893405; called by muse, mutect2, varscan2
- LRIF1 | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.634); catalogued as rs1362366205, COSV100870793; called by muse, mutect2, varscan2
- LRRC8E | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757613174, COSV100142608; called by muse, mutect2, varscan2
- MEMO1 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 98/377 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99703636; called by muse, mutect2, varscan2
- MMS22L | c.698-1G>A p.X233_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as rs767303030; called by muse, mutect2
- MORC1 | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99224989; called by muse, mutect2
- MTTP | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs148696330, COSV55505486; called by muse, mutect2, varscan2
- MYH3 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV99877680; called by muse, mutect2, varscan2
- NEGR1 | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV100747038, COSV63248672; called by muse, mutect2
- NLRP3 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV100275210; called by muse, mutect2, varscan2
- NPAT | c.1532C>A p.S511* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as COSV99585744; called by muse, mutect2, varscan2
- OR5H6 | c.95G>A p.G32E (on ENST00000642105; = p.G16E on NM_001005479.2) | Missense Mutation (SNP) | VAF 232/460 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765251519, COSV67351343; called by muse, mutect2, varscan2
- OR6B3 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100096880, COSV60113862; called by muse, mutect2, varscan2
- OR6Q1 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV100109315; called by muse, mutect2, varscan2
- OR6X1 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV100020430; called by muse, mutect2, varscan2
- PCDH11X | c.1531C>A p.P511T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV100007943; called by muse, mutect2, varscan2
- PDE2A | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs773937555, COSV100557600; called by muse, mutect2, varscan2
- PDE8B | c.2005A>G p.N669D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99366068; called by muse, mutect2, varscan2
- PDGFRA | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV99955387; called by muse, mutect2, varscan2
- PEG3 | c.2887C>A p.R963S | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.018); catalogued as COSV99687124; called by muse, mutect2, varscan2
- PHTF1 | c.2278A>G p.I760V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV100852264; called by muse, mutect2, varscan2
- PIGX | c.310A>T p.I104L | Missense Mutation (SNP) | VAF 61/411 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99582137; called by muse, mutect2, varscan2
- PINX1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs368843905; called by muse, mutect2, varscan2
- POTEE | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.82); catalogued as rs1443877295, COSV58228042; called by muse, mutect2, varscan2
- PPFIA2 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs756811275, COSV61044575, COSV61052417; called by muse, mutect2, varscan2
- PPM1L | c.790T>G p.S264A | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99861239; called by muse, mutect2, varscan2
- PPP1R12A | c.1308G>C p.W436C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99699944; called by muse, mutect2, varscan2
- PRDM16 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99575384; called by muse, mutect2, varscan2
- PSME3IP1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1213586579, COSV58429782; called by muse, mutect2, varscan2
- RARG | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100553270; called by muse, mutect2, varscan2
- RASAL2 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs753745884, COSV100862329; called by muse, mutect2, varscan2
- RBM11 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101271176; called by muse, mutect2, varscan2
- RESF1 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57020011; called by muse, mutect2, varscan2
- RIPOR1 | c.676G>A p.D226N (on ENST00000379312 / NM_001193522.2; = p.D222N on NM_024519.4) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99242508; called by muse, mutect2, varscan2
- SEMA5B | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as rs1254071286, COSV52109683, COSV99530752; called by muse, mutect2
- SHROOM4 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1168007152, COSV99172988; called by muse, mutect2, varscan2
- SI | c.3418C>T p.P1140S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV100013834, COSV100016075; called by muse, mutect2, varscan2
- SIGLEC9 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs771199882, COSV99142397; called by muse, mutect2, varscan2
- SLC12A1 | c.2435T>G p.I812R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs201516084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A2 | c.1589A>C p.E530A | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100871189; called by muse, mutect2, varscan2
- SLCO4C1 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.158); catalogued as rs1404559111, COSV100194453; called by muse, mutect2, varscan2
- SMC2 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 60/332 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1401285860, COSV53958566; called by muse, mutect2, varscan2
- SPEN | c.4049G>A p.R1350K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV101004990; called by muse, mutect2, varscan2
- SRRD | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs756111926, COSV53225974; called by muse, mutect2, varscan2
- SULF1 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99482011; called by muse, mutect2, varscan2
- TCF7 | c.377A>T p.N126I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV100389748; called by muse, mutect2, varscan2
- TESPA1 | c.466A>T p.K156* (on ENST00000316577 / NM_001098815.3; = p.K18* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | catalogued as COSV100344841; called by muse, mutect2, varscan2
- TESPA1 | c.465C>G p.D155E (on ENST00000316577 / NM_001098815.3; = p.D17E on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.825); catalogued as COSV100344846; called by muse, mutect2, varscan2
- THAP6 | c.156T>G p.I52M | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.009); catalogued as rs1187843603, COSV100185707; called by muse, mutect2, varscan2
- TNR | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs376736413; called by muse, mutect2, varscan2
- TRAFD1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99986769; called by muse, mutect2, varscan2
- TSSK2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427113895, COSV99350602; called by muse, mutect2, varscan2
- TTN | c.84788G>C p.R28263P (on ENST00000591111; = p.R20839P on NM_003319.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | PolyPhen probably damaging (0.999); catalogued as rs397517744, COSV100593212; called by muse, mutect2, varscan2
- UBR2 | c.1354C>G p.R452G | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.532); catalogued as COSV100867356, COSV65749689; called by muse, mutect2, varscan2
- VAT1 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1205795309, COSV100849672; called by muse, mutect2, varscan2
- ZNF276 | c.1685G>A p.R562Q (on ENST00000443381 / NM_001113525.2; = p.R487Q on NM_152287.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs780532307, COSV57070802; called by muse, mutect2, varscan2
- ZNF430 | c.1436A>T p.H479L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99841547; called by muse, mutect2, varscan2
- ZNF493 | c.1925A>G p.E642G | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV100828553; called by muse, mutect2, varscan2
- ZNF521 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV100831385; called by muse, mutect2, varscan2
- KLC3 | c.755dup p.N253Qfs*22 | Frame Shift Ins (INS) | VAF 10/19 reads (53%) | called by mutect2, varscan2
- MIGA1 | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.724); called by muse, mutect2
- ORMDL2 | c.145del p.W49Gfs*3 | Frame Shift Del (DEL) | VAF 37/107 reads (35%) | called by mutect2, pindel, varscan2
- SLC6A14 | c.649del p.Y217Ifs*13 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- ZFYVE16 | c.666T>A p.S222R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.039); called by muse, mutect2
- ACACA | c.1704C>T p.F568= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs910989117; called by muse, mutect2, varscan2
- AHNAK | c.369A>G p.E123= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99945448; called by muse, mutect2, varscan2
- ANKRD27 | c.1665G>A p.S555= | Silent (SNP) | VAF 73/138 reads (53%) | catalogued as rs138473952; called by muse, mutect2, varscan2
- ASTL | c.150C>T p.S50= | Silent (SNP) | VAF 67/177 reads (38%) | catalogued as rs142516442; called by muse, mutect2, varscan2
- BRINP3 | c.102T>A p.A34= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100818283; called by muse, mutect2, varscan2
- CER1 | c.786C>T p.I262= | Silent (SNP) | VAF 44/66 reads (67%) | catalogued as rs368200307; called by muse, mutect2, varscan2
- CLMN | c.1749T>C p.V583= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV100112035; called by muse, mutect2, varscan2
- CNR1 | c.708G>A p.A236= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs577054667, COSV62988555; called by muse, mutect2, varscan2
- COPA | c.141T>C p.F47= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV99614535; called by muse, varscan2
- CSMD3 | c.9450T>C p.P3150= (on ENST00000297405 / NM_001363185.1; = p.P2981= on NM_052900.3) | Silent (SNP) | VAF 31/174 reads (18%) | catalogued as COSV99823808; called by muse, mutect2, varscan2
- DUOXA1 | c.942C>A p.P314= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV99972768; called by muse, mutect2, varscan2
- ECT2 | c.1326C>T p.S442= (on ENST00000392692 / NM_001349098.2; = p.S411= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 45/141 reads (32%) | catalogued as rs776813098, COSV99220874; called by muse, mutect2, varscan2
- EPN1 | c.1314G>A p.A438= (on ENST00000270460 / NM_001321263.1; = p.A412= on NM_013333.3) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs746504881, COSV50035874; called by muse, mutect2, varscan2
- EPN2 | c.1215C>T p.P405= | Silent (SNP) | VAF 52/87 reads (60%) | catalogued as COSV100127328; called by muse, mutect2, varscan2
- FLRT1 | c.1044C>T p.A348= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs140908634; called by muse, mutect2, varscan2
- GIN1 | c.165A>G p.K55= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV101204271; called by muse, mutect2
- GRID2 | c.2472C>T p.G824= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs771961200, COSV56212046, COSV56245706; called by muse, mutect2, varscan2
- GTDC1 | c.87C>T p.V29= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs146914833; called by muse, mutect2, varscan2
- HERC4 | c.2868A>G p.T956= (on ENST00000395198 / NM_022079.3; = p.T948= on NM_015601.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99516500; called by muse, mutect2, varscan2
- HS6ST2 | c.201C>T p.L67= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100896935; called by muse, mutect2
- ITPRID1 | c.1848C>A p.A616= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV100085573; called by muse, mutect2, varscan2
- KBTBD2 | c.1464C>T p.P488= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as COSV100406371; called by muse, mutect2, varscan2
- MCM4 | c.372C>G p.G124= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100031214; called by muse, mutect2, varscan2
- MEX3D | c.678G>A p.V226= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV101183457; called by muse, mutect2, varscan2
- MUC2 | c.195C>T p.S65= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs771628651; called by muse, mutect2, varscan2
- NFU1 | c.636C>T p.S212= (on ENST00000410022 / NM_001002755.4; = p.S188= on NM_015700.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/274 reads (22%) | catalogued as COSV100361025; called by muse, mutect2, varscan2
- NOX3 | c.450C>T p.N150= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs774496858, COSV99030857, COSV99342675; called by muse, mutect2, varscan2
- NR2F1 | c.1212C>T p.R404= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as rs761244180, COSV59068035; called by muse, mutect2, varscan2
- OGFRL1 | c.627G>A p.L209= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100965708; called by muse, mutect2, varscan2
- OR10V1 | c.663C>T p.F221= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs146924217, COSV100275529; called by muse, mutect2, varscan2
- OTUD6A | c.696C>A p.P232= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV100610922, COSV57972773; called by muse, mutect2, varscan2
- PCDH10 | c.507G>A p.L169= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV99992904; called by muse, mutect2, varscan2
- PCDHA1 | c.1302G>A p.S434= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as rs144742806, COSV65377815; called by muse, mutect2, varscan2
- PCDHAC1 | c.741C>A p.P247= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99164973; called by muse, mutect2, varscan2
- PEX11A | c.120G>A p.K40= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as rs1323187808, COSV99175461; called by muse, mutect2, varscan2
- PIK3AP1 | c.381C>T p.D127= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as rs1206726427, COSV100225474; called by muse, mutect2, varscan2
- PKD2 | c.2244G>A p.K748= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as COSV99416792; called by muse, mutect2, varscan2
- PNN | c.780G>A p.Q260= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99397024, COSV99397436; called by muse, mutect2, varscan2
- PPFIA2 | c.1932C>G p.S644= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs778364645, COSV100331571, COSV61058615; called by muse, mutect2, varscan2
- PTGFRN | c.1245C>G p.S415= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV101277240, COSV67797768; called by muse, mutect2, varscan2
- RAD51D | c.621G>T p.S207= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as rs749859221, COSV100238952; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM15B | c.927G>T p.L309= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100081893; called by muse, mutect2, varscan2
- RESF1 | c.2034C>T p.S678= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs777193605, COSV100440074; called by muse, mutect2, varscan2
- SDK1 | c.1623G>T p.A541= | Silent (SNP) | VAF 85/265 reads (32%) | catalogued as rs370707319, COSV101268723; called by muse, mutect2, varscan2
- SLC22A1 | c.999A>T p.S333= | Silent (SNP) | VAF 63/148 reads (43%) | catalogued as COSV100266379; called by muse, mutect2, varscan2
- SLC36A3 | c.1041C>T p.H347= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs780426921, COSV100077322, COSV58858143; called by muse, mutect2, varscan2
- SNCAIP | c.1818G>T p.R606= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99746968; called by muse, mutect2, varscan2
- STRADB | c.867G>A p.L289= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV99524267; called by muse, mutect2, varscan2
- SULT2B1 | c.528G>C p.L176= (on ENST00000201586 / NM_177973.2; = p.L161= on NM_004605.2) | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV99572041; called by muse, mutect2
- TCIRG1 | c.1293C>T p.A431= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs372063415, COSV99693088; called by muse, mutect2, varscan2
- TK1 | c.570C>T p.F190= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV99857133; called by muse, mutect2, varscan2
- TMEM161A | c.732C>T p.F244= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99365349; called by muse, mutect2, varscan2
- TOLLIP | c.672C>T p.N224= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs374900667; called by muse, mutect2, varscan2
- TRPT1 | c.483A>G p.G161= (on ENST00000317459 / NM_001160393.1; = p.G112= on NM_031472.4) | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99655624; called by muse, mutect2, varscan2
- WDR72 | c.51C>T p.P17= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV100854175; called by muse, mutect2, varscan2
- MIR514A3 | n.42T>G | RNA (SNP) | VAF 29/206 reads (14%) | called by muse, mutect2, varscan2
- MYH7B | c.2100+92C>G | Intron (SNP) | VAF 46/79 reads (58%) | catalogued as COSV99482239; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185109G>A | Intron (SNP) | VAF 112/315 reads (36%) | catalogued as rs753586841, COSV100299424; called by muse, mutect2, varscan2
- SNRPN | chr15:24979989 C>G | 3'Flank (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
